Somatic mutation profile of tumor specimen MBCProject_3710_T1_WES (aliquot MBCProject_3710_T1_WES_1) from CMI case MBCProject_3710, project CMI-MBC: Count Me In (CMI): The Metastatic Breast Cancer (MBC) Project. Sex at birth: female; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; Age at diagnosis: 34.5 years (12,592 days).
Specimen MBCProject_3710_T1_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Breast; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7d5b0e90-c8ec-47a7-82bc-33bb4c984062.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MBCProject_3710_SALIVA (Saliva), aliquot MBCProject_3710_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0e3e42a6-a540-4c3b-a33b-741569d73fba

The open-access MAF lists 89 somatic variants for this specimen: 59 protein-altering or splice-affecting, 19 silent, 11 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 54, Silent 19, Intron 4, RNA 3, Nonsense Mutation 3, 5'Flank 2, In Frame Del 1, 3'Flank 1, 3'UTR 1, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAMTS7 | c.356C>T p.A119V | Missense Mutation (SNP) | VAF 42/214 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.132); catalogued as rs775057855; called by muse, mutect2, varscan2
- BICDL1 | c.1357C>G p.R453G | Missense Mutation (SNP) | VAF 69/238 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.806); catalogued as COSV57493948; called by muse, mutect2, varscan2
- CLEC1A | c.760C>T p.R254C | Missense Mutation (SNP) | VAF 24/235 reads (10%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.519); catalogued as rs776906519, COSV59533191; called by muse, mutect2, varscan2
- CSMD3 | c.6229C>A p.Q2077K (on ENST00000297405 / NM_001363185.1; = p.Q1973K on NM_052900.3) | Missense Mutation (SNP) | VAF 71/644 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.02); catalogued as rs923089836, COSV52165547, COSV52353929; called by muse, mutect2, varscan2
- EPX | c.418C>T p.R140C | Missense Mutation (SNP) | VAF 14/267 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.326); catalogued as rs1454539064; called by muse, mutect2
- FRY | c.4465C>G p.Q1489E | Missense Mutation (SNP) | VAF 62/302 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.549); catalogued as COSV100969051; called by muse, varscan2
- MATK | c.757G>A p.E253K (on ENST00000310132 / NM_139355.3; = p.E254K on NM_002378.4) | Missense Mutation (SNP) | VAF 20/176 reads (11%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.903); catalogued as rs1568405010; called by muse, mutect2, varscan2
- NFKBIZ | c.213_215del p.S72del | In Frame Del (DEL) | VAF 30/196 reads (15%) | catalogued as rs1252296200; called by pindel, varscan2
- NUTM1 | c.298G>A p.E100K | Missense Mutation (SNP) | VAF 43/255 reads (17%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.946); catalogued as COSV61548354; called by muse, mutect2, varscan2
- PLPP7 | c.349G>A p.G117S | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT tolerated (0.38); PolyPhen benign (0.313); catalogued as rs780826946; called by muse, mutect2, varscan2
- PREX1 | c.4285C>T p.H1429Y | Missense Mutation (SNP) | VAF 38/247 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.506); catalogued as rs772185752; called by muse, mutect2, varscan2
- PRR5-ARHGAP8 | c.1541G>A p.R514H (on ENST00000352766; = p.R435H on NM_181334.5) | Missense Mutation (SNP) | VAF 68/223 reads (30%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.013); catalogued as rs78823624; called by muse, mutect2, varscan2
- PTPRZ1 | c.856C>T p.R286* | Nonsense Mutation (SNP) | VAF 23/165 reads (14%) | catalogued as rs771283585, COSV66436171, COSV66436709; called by muse, mutect2, varscan2
- RBM10 | c.2342C>T p.S781L | Missense Mutation (SNP) | VAF 73/428 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1556782040, COSV61308142, COSV61309495; called by muse, mutect2, varscan2
- SGK3 | c.1115A>G p.N372S | Missense Mutation (SNP) | VAF 40/222 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.071); catalogued as rs952010662; called by muse, mutect2, varscan2
- SLC35B4 | c.383C>T p.S128F | Missense Mutation (SNP) | VAF 22/240 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV65985577; called by muse, mutect2
- SPTBN4 | c.1492G>A p.E498K | Missense Mutation (SNP) | VAF 32/186 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.688); catalogued as rs775127507, COSV100151792; called by muse, mutect2, varscan2
- SUSD1 | c.1003C>T p.R335W | Missense Mutation (SNP) | VAF 20/132 reads (15%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.794); catalogued as rs747833554, COSV62584451; called by muse, mutect2
- SYN1 | c.700C>T p.R234* | Nonsense Mutation (SNP) | VAF 72/506 reads (14%) | catalogued as COSV55979499; called by muse, mutect2, varscan2
- TEX13C | c.2518G>A p.D840N | Missense Mutation (SNP) | VAF 60/489 reads (12%) | SIFT tolerated (0.61); PolyPhen possibly damaging (0.836); catalogued as rs1189703205; called by muse, mutect2, varscan2
- TMEM62 | c.662G>A p.R221Q | Missense Mutation (SNP) | VAF 17/152 reads (11%) | SIFT tolerated (0.91); PolyPhen benign (0); catalogued as rs752946919; called by muse, mutect2, varscan2
- TMEM63A | c.1665C>G p.F555L | Missense Mutation (SNP) | VAF 23/179 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs547841434; called by muse, mutect2, varscan2
- TNFSF9 | c.182C>T p.S61L | Missense Mutation (SNP) | VAF 21/145 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV55537734; called by muse, mutect2, varscan2
- USP35 | c.250C>T p.R84C | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.353); catalogued as COSV71573284; called by muse, mutect2, varscan2
- WT1 | c.775G>A p.G259S | Missense Mutation (SNP) | VAF 30/614 reads (5%) | SIFT tolerated, low confidence (0.64); PolyPhen benign (0.018); catalogued as COSV60072100; called by muse, mutect2
- ZNF275 | c.565C>T p.R189W | Missense Mutation (SNP) | VAF 52/192 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as rs1556961711; called by muse, mutect2, varscan2
- ZNF461 | c.739G>A p.E247K | Missense Mutation (SNP) | VAF 18/89 reads (20%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs375529284; called by muse, mutect2, varscan2
- ZNF804B | c.2091G>C p.K697N | Missense Mutation (SNP) | VAF 27/181 reads (15%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as rs1309610402; called by muse, mutect2, varscan2
- ACACA | c.4607A>T p.Y1536F | Missense Mutation (SNP) | VAF 104/818 reads (13%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.72); called by muse, varscan2
- ALOX15 | c.38C>T p.S13L | Missense Mutation (SNP) | VAF 40/157 reads (25%) | SIFT tolerated (0.16); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- BAZ1A | c.4171G>C p.V1391L | Missense Mutation (SNP) | VAF 30/125 reads (24%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- CCDC175 | c.1960G>A p.D654N | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT tolerated (0.18); PolyPhen benign (0.25); called by muse, mutect2, varscan2
- CMPK2 | c.1045C>T p.L349F | Missense Mutation (SNP) | VAF 127/327 reads (39%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.787); called by muse, mutect2, varscan2
- COL17A1 | c.272C>T p.P91L | Missense Mutation (SNP) | VAF 173/701 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.84); called by muse, mutect2, varscan2
- CTXN2 | c.39G>C p.M13I | Missense Mutation (SNP) | VAF 10/205 reads (5%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0.258); called by muse, mutect2
- DCHS1 | c.6124G>A p.D2042N | Missense Mutation (SNP) | VAF 17/465 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- DOCK4 | c.4727T>C p.L1576P | Missense Mutation (SNP) | VAF 16/84 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- DPYD | c.2458C>G p.Q820E | Missense Mutation (SNP) | VAF 46/321 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- EFCAB5 | c.139G>C p.E47Q | Missense Mutation (SNP) | VAF 30/208 reads (14%) | SIFT tolerated, low confidence (0.11); PolyPhen possibly damaging (0.802); called by muse, mutect2, varscan2
- EIF4A1 | c.553G>C p.D185H | Missense Mutation (SNP) | VAF 25/129 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- ESYT2 | c.2378C>T p.T793I (on ENST00000613624; = p.T717I on NM_020728.3) | Missense Mutation (SNP) | VAF 41/285 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- FAM166A | c.272G>C p.S91T | Missense Mutation (SNP) | VAF 18/117 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- GCNA | c.19G>T p.E7* | Nonsense Mutation (SNP) | VAF 35/262 reads (13%) | called by muse, mutect2, varscan2
- GFM2 | c.313G>A p.D105N | Missense Mutation (SNP) | VAF 21/123 reads (17%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.457); called by muse, mutect2, varscan2
- HIP1R | c.2452G>C p.E818Q | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.564); called by muse, mutect2, varscan2
- IGHD | c.100C>T p.H34Y | Missense Mutation (SNP) | VAF 16/490 reads (3%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2
- JAG1 | c.1114T>G p.S372A | Missense Mutation (SNP) | VAF 100/237 reads (42%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- KCNV1 | c.202C>A p.L68M | Missense Mutation (SNP) | VAF 102/333 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LRRC7 | c.4453T>A p.F1485I (on ENST00000651989 / NM_001370785.2; = p.F1405I on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/128 reads (11%) | SIFT tolerated (0.82); PolyPhen possibly damaging (0.449); called by muse, varscan2
- MKNK2 | c.1206G>A p.M402I | Missense Mutation (SNP) | VAF 22/93 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- MRPS12 | c.416G>C p.*139Sext*14 | Nonstop Mutation (SNP) | VAF 23/170 reads (14%) | called by muse, mutect2, varscan2
- MYLK | c.2828G>A p.R943K | Missense Mutation (SNP) | VAF 71/373 reads (19%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.827); called by muse, mutect2, varscan2
- NFATC3 | c.1338T>A p.H446Q | Missense Mutation (SNP) | VAF 18/114 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- NKX1-1 | c.592G>A p.E198K | Missense Mutation (SNP) | VAF 23/149 reads (15%) | SIFT deleterious, low confidence (0.02); called by muse, mutect2, varscan2
- PDS5B | c.70G>C p.D24H | Missense Mutation (SNP) | VAF 66/251 reads (26%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- PHIP | c.3452C>T p.P1151L | Missense Mutation (SNP) | VAF 20/154 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PLA2G4A | c.982C>G p.L328V | Missense Mutation (SNP) | VAF 254/745 reads (34%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.532); called by muse, varscan2
- THBS2 | c.1165G>C p.E389Q | Missense Mutation (SNP) | VAF 12/148 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.861); called by muse, mutect2
- TMEM63B | c.1151G>A p.C384Y | Missense Mutation (SNP) | VAF 23/119 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.865); called by muse, mutect2, varscan2
- ARHGEF12 | c.1929T>C p.S643= | Silent (SNP) | VAF 176/420 reads (42%) | catalogued as rs934235622; called by muse, mutect2, varscan2
- BCL3 | c.1065C>T p.I355= | Silent (SNP) | VAF 20/260 reads (8%) | called by muse, mutect2
- CCDC66 | c.1902G>A p.E634= (on ENST00000394672 / NM_001353147.1; = p.E600= on NM_001012506.5 and 6 other RefSeq transcripts) | Silent (SNP) | VAF 16/118 reads (14%) | called by muse, mutect2, varscan2
- CELF3 | c.678C>T p.L226= | Silent (SNP) | VAF 21/342 reads (6%) | called by muse, mutect2
- FGF5 | c.339C>T p.H113= | Silent (SNP) | VAF 15/80 reads (19%) | catalogued as rs373878896; called by muse, mutect2
- FRY | c.4557C>T p.F1519= | Silent (SNP) | VAF 51/208 reads (25%) | catalogued as COSV66570990; called by muse, varscan2
- HEG1 | c.2596C>T p.L866= | Silent (SNP) | VAF 43/248 reads (17%) | catalogued as rs1357098810; called by muse, mutect2, varscan2
- IL31RA | c.621C>T p.F207= | Silent (SNP) | VAF 38/394 reads (10%) | catalogued as rs139299832; called by muse, mutect2, varscan2
- LRFN4 | c.405C>T p.I135= | Silent (SNP) | VAF 15/63 reads (24%) | catalogued as rs1341069537, COSV58920542, COSV58923384; called by muse, mutect2, varscan2
- NID1 | c.3019C>T p.L1007= | Silent (SNP) | VAF 97/871 reads (11%) | called by muse, mutect2, varscan2
- NUP188 | c.4377C>T p.L1459= | Silent (SNP) | VAF 12/237 reads (5%) | called by muse, mutect2
- OLIG2 | c.843G>A p.A281= | Silent (SNP) | VAF 3/37 reads (8%) | catalogued as rs1021985920; called by muse, mutect2
- PALD1 | c.33G>A p.T11= | Silent (SNP) | VAF 24/438 reads (5%) | catalogued as rs373834281; called by muse, mutect2
- PCDHB15 | c.2022A>T p.P674= | Silent (SNP) | VAF 34/682 reads (5%) | catalogued as rs781843545; called by muse, mutect2
- PPP6R1 | c.1791C>G p.L597= | Silent (SNP) | VAF 38/304 reads (13%) | catalogued as rs781182613; called by muse, varscan2
- PSMD12 | c.96G>C p.A32= | Silent (SNP) | VAF 52/319 reads (16%) | catalogued as COSV62065163; called by muse, mutect2, varscan2
- SUGP1 | c.1062C>T p.P354= | Silent (SNP) | VAF 12/64 reads (19%) | catalogued as rs768801154; called by muse, mutect2, varscan2
- TRPC4 | c.177T>C p.F59= | Silent (SNP) | VAF 16/101 reads (16%) | called by muse, mutect2, varscan2
- TTC6 | c.2223C>T p.L741= | Silent (SNP) | VAF 20/240 reads (8%) | called by muse, mutect2
- AL353804.7 | chrX:73848041 G>A | 5'Flank (SNP) | VAF 16/441 reads (4%) | called by muse, mutect2
- CCDC88B | c.4306+49A>T | Intron (SNP) | VAF 20/92 reads (22%) | called by muse, mutect2, varscan2
- CRYBB1 | c.300-11C>G | Intron (SNP) | VAF 69/438 reads (16%) | called by muse, mutect2, varscan2
- FAM172BP | n.82G>C | RNA (SNP) | VAF 10/54 reads (19%) | called by mutect2, varscan2
- FAM221A | chr7:23680174 G>C | 5'Flank (SNP) | VAF 57/342 reads (17%) | catalogued as rs938733618; called by muse, mutect2, varscan2
- LAMTOR4 | chr7:100155885 C>T | 3'Flank (SNP) | VAF 18/172 reads (10%) | catalogued as rs777987224, COSV100385492; called by muse, mutect2, varscan2
- MIR509-2 | n.42G>T | RNA (SNP) | VAF 61/178 reads (34%) | called by muse, mutect2, varscan2
- SPG7 | c.1642+1110G>A | Intron (SNP) | VAF 12/102 reads (12%) | catalogued as rs150306537; called by muse, mutect2, varscan2
- TAZ | c.646+46G>T | Intron (SNP) | VAF 27/218 reads (12%) | catalogued as COSV54797248; called by muse, mutect2, varscan2
- TG | c.*32G>A | 3'UTR (SNP) | VAF 52/546 reads (10%) | catalogued as rs760309222; called by muse, mutect2
- UBE2DNL | n.565T>C | RNA (SNP) | VAF 30/214 reads (14%) | called by muse, mutect2, varscan2
